Somatic mutation profile of tumor specimen MP2PRT-PATJIZ-TBP1-A (aliquot MP2PRT-PATJIZ-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATJIZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,642 days).
Specimen MP2PRT-PATJIZ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad39a152-a9e2-4ff1-a1f2-8b17d848cde4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJIZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJIZ-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40613e80-a5a2-4cd3-b366-b06668d8fd7f

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Frame Shift Ins 6, Frame Shift Del 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/274 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 45/301 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKFY1 | c.2153G>A p.G718D (on ENST00000341657 / NM_001330063.2; = p.G719D on NM_016376.5) | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as rs1225068676; called by muse, mutect2, varscan2
- ATP13A1 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 49/424 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.086); catalogued as rs775106633; called by muse, mutect2, varscan2
- BORCS8 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 58/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99364544; called by muse, mutect2, varscan2
- C1QTNF9B | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 40/523 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65944211; called by muse, mutect2
- CIT | c.5785T>C p.Y1929H | Missense Mutation (SNP) | VAF 25/447 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99951446; called by muse, mutect2
- CPXCR1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 57/680 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV52163598; called by muse, mutect2
- CREBBP | c.4448T>A p.I1483N | Missense Mutation (SNP) | VAF 65/430 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113979, COSV52115041, COSV52119010; called by muse, mutect2, varscan2
- CSH2 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 66/1238 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs756873090, COSV61080026; called by muse, mutect2
- GFPT2 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs368601222; called by muse, mutect2, varscan2
- HYOU1 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV68215289; called by muse, mutect2, varscan2
- JAKMIP1 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 87/675 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1291124278, COSV101290882, COSV68954106; called by muse, mutect2, varscan2
- KCNS2 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as rs377211918; called by muse, mutect2, varscan2
- OR5K1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs370192014, COSV60303652; called by muse, mutect2, varscan2
- PLA2G15 | c.695dup p.V233Rfs*47 | Frame Shift Ins (INS) | VAF 42/281 reads (15%) | catalogued as rs763871300; called by mutect2, varscan2
- SERPINA4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs540841872, COSV54069263; called by muse, mutect2, varscan2
- SETD2 | c.3896A>G p.Y1299C | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV57433086; called by muse, mutect2
- SHROOM3 | c.2791G>A p.A931T | Missense Mutation (SNP) | VAF 94/718 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867064604; called by muse, varscan2
- SOX5 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 32/465 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV100508266, COSV58640385; called by muse, mutect2
- STK31 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs201698675, COSV63458786; called by muse, mutect2
- VPS13C | c.10006C>T p.H3336Y (on ENST00000644861 / NM_020821.3; = p.H3293Y on NM_017684.5) | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774044358; called by muse, mutect2, varscan2
- ZBTB2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.272); catalogued as rs767336276, COSV100287530, COSV57314121; called by muse, mutect2, varscan2
- ARID5B | c.635dup p.I213Hfs*18 | Frame Shift Ins (INS) | VAF 44/345 reads (13%) | called by mutect2, pindel, varscan2
- BICRA | c.1156del p.A386Rfs*12 | Frame Shift Del (DEL) | VAF 64/474 reads (14%) | called by mutect2, pindel, varscan2
- COL4A4 | c.1505dup p.G503Wfs*12 | Frame Shift Ins (INS) | VAF 52/396 reads (13%) | called by mutect2, pindel, varscan2
- ELP4 | c.936A>C p.K312N (on ENST00000350638; = p.K311N on NM_019040.5) | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.258); called by muse, mutect2
- ESR1 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 32/517 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- EXOC6 | c.2136T>A p.D712E | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FGL2 | c.19_20insCC p.Y7Sfs*4 | Frame Shift Ins (INS) | VAF 31/229 reads (14%) | called by mutect2, pindel, varscan2
- GAL3ST1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 143/508 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GAL3ST4 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 69/519 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.351_353del p.P117del | In Frame Del (DEL) | VAF 10/100 reads (10%) | called by pindel*, varscan2
- KMT2D | c.6763_6764del p.L2255Gfs*4 | Frame Shift Del (DEL) | VAF 97/546 reads (18%) | called by mutect2, pindel, varscan2
- MYH8 | c.2591A>C p.D864A | Missense Mutation (SNP) | VAF 54/520 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- MYT1L | c.2831A>G p.K944R | Missense Mutation (SNP) | VAF 35/333 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- POGK | c.689dup p.N230Kfs*89 | Frame Shift Ins (INS) | VAF 56/346 reads (16%) | called by mutect2, varscan2
- QDPR | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 32/866 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- RASGRF2 | c.3671T>A p.L1224Q | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SATL1 | c.524G>A p.R175K (on ENST00000395409; = p.R362K on NM_001012980.2) | Missense Mutation (SNP) | VAF 68/847 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SEC14L5 | c.59T>C p.M20T | Missense Mutation (SNP) | VAF 51/451 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- STARD8 | c.2267T>A p.L756Q | Missense Mutation (SNP) | VAF 66/629 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAS2R3 | c.297dup p.A100Cfs*29 | Frame Shift Ins (INS) | VAF 50/569 reads (9%) | called by mutect2, pindel
- TTC30B | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 84/514 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YY1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 41/360 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZNF354C | c.80T>C p.L27S | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARFGEF1 | c.540T>C p.N180= | Silent (SNP) | VAF 47/300 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.4665C>T p.V1555= (on ENST00000310343 / NM_001378025.1; = p.V1206= on NM_014715.4) | Silent (SNP) | VAF 94/382 reads (25%) | catalogued as rs770024373; called by muse, mutect2, varscan2
- BCAN | c.2616G>T p.V872= | Silent (SNP) | VAF 52/294 reads (18%) | called by muse, mutect2, varscan2
- CHST8 | c.294G>A p.P98= | Silent (SNP) | VAF 76/504 reads (15%) | catalogued as rs750673635, COSV99381469; called by muse, mutect2, varscan2
- COL1A2 | c.2271C>T p.G757= | Silent (SNP) | VAF 62/376 reads (16%) | catalogued as rs750379228, COSV51956665; called by muse, mutect2, varscan2
- DDX6 | c.1197T>C p.D399= | Silent (SNP) | VAF 32/219 reads (15%) | called by muse, mutect2, varscan2
- IRS2 | c.3396C>T p.G1132= | Silent (SNP) | VAF 105/800 reads (13%) | catalogued as COSV65480661; called by muse, mutect2, varscan2
- MTM1 | c.1591T>C p.L531= | Silent (SNP) | VAF 28/391 reads (7%) | called by muse, mutect2
- MYO19 | c.1029C>T p.D343= | Silent (SNP) | VAF 72/914 reads (8%) | catalogued as rs1032683198; called by muse, mutect2
- NEB | c.18096G>A p.P6032= | Silent (SNP) | VAF 56/374 reads (15%) | catalogued as rs775027154, COSV50821990; called by muse, mutect2, varscan2
- VIL1 | c.1266T>C p.Y422= | Silent (SNP) | VAF 46/407 reads (11%) | catalogued as rs1210046855; called by muse, mutect2, varscan2
- VSTM2B | c.306C>T p.R102= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV100139592; called by muse, varscan2
- ZNF41 | c.1323C>T p.C441= | Silent (SNP) | VAF 49/452 reads (11%) | catalogued as rs746076782, COSV57441918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS6KA6 | c.81+1711A>G | Intron (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
